Somatic mutation profile of tumor specimen TARGET-10-PARDDV-09A (aliquot TARGET-10-PARDDV-09A-01D) from TARGET case TARGET-10-PARDDV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,193 days).
Specimen TARGET-10-PARDDV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 560110c0-df0a-4350-85fd-382389e81943.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDDV-10A (Blood Derived Normal), aliquot TARGET-10-PARDDV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9a94a47-b88c-4204-a004-106bdc91abef

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 3, Silent 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FZD9 | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.935); catalogued as COSV59988235; called by muse, mutect2, varscan2
- GNAS | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs773531749; called by muse, mutect2, varscan2
- PTGFR | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769693596, COSV100882265; called by muse, mutect2, varscan2
- SLC7A14 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs750600837, COSV51586002; called by muse, mutect2, varscan2
- ABCB1 | c.3622A>G p.T1208A | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ASXL3 | c.4760C>A p.A1587D | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GPR158 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714674 ACACTGTGTCT>CCCTC | Missense Mutation (DEL) | VAF 15/20 reads (75%) | called by pindel, varscan2*
- IGHV1-69D | chr14:106762084 ACACTGTGTCT>CCCTC | Missense Mutation (DEL) | VAF 41/53 reads (77%) | called by pindel, varscan2*
- PAX5 | c.148delinsGGGGGGC p.V49_R50insGG | In Frame Ins (INS) | VAF 29/81 reads (36%) | called by pindel, varscan2*
- EML3 | c.2265G>A p.V755= | Silent (SNP) | VAF 20/48 reads (42%) | called by mutect2, varscan2
- EML5 | c.3771C>T p.G1257= | Silent (SNP) | VAF 51/135 reads (38%) | catalogued as rs1024660402, COSV61347905; called by muse, mutect2, varscan2
- SERPINB3 | c.303G>C p.L101= | Silent (SNP) | VAF 39/147 reads (27%) | catalogued as COSV52190302; called by muse, mutect2, varscan2
- FCGR3B | c.62-62G>A | Intron (SNP) | VAF 4/15 reads (27%) | catalogued as rs867978168; called by muse, mutect2
- HARS2 | c.633+64C>T | Intron (SNP) | VAF 77/204 reads (38%) | catalogued as rs1374224722; called by muse, mutect2, varscan2
- TPK1 | c.355-15424C>A | Intron (SNP) | VAF 62/139 reads (45%) | catalogued as COSV100765344; called by muse, mutect2, varscan2
